Somatic mutation profile of tumor specimen C3L-07571-54 (aliquot CPT0450420002) from CPTAC case C3L-07571, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 78.7 years (28,754 days).
Specimen C3L-07571-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd2db534-5dd0-4234-8f0d-f7a2541de009.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07571-50 (Buccal Cell Normal), aliquot CPT0450390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c1ab09e-035c-46a3-9e1a-3683f957914a

The open-access MAF lists 7 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Intron 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RBM27 | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.011); called by muse, varscan2
- USP47 | c.1819T>A p.C607S (on ENST00000399455 / NM_001372095.1; = p.C519S on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- FBXL18 | c.1383C>T p.S461= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs201998941; called by muse, mutect2, varscan2
- KALRN | c.8814G>C p.L2938= (on ENST00000360013 / NM_001024660.4; = p.L1241= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 139/304 reads (46%) | called by muse, mutect2, varscan2
- MAGEC1 | c.3282C>T p.T1094= | Silent (SNP) | VAF 39/42 reads (93%) | catalogued as rs771850104, COSV53576412, COSV53580076; called by muse, mutect2, varscan2
- DLG3 | c.840+42G>A | Intron (SNP) | VAF 24/26 reads (92%) | called by muse, mutect2, varscan2
- TNS1 | c.1055-10575G>A | Intron (SNP) | VAF 54/132 reads (41%) | catalogued as rs1305413903; called by muse, mutect2, varscan2
